Surgical pathology report (de-identified scan), TCGA case TCGA-29-1692, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Duke, specimen TCGA-29-1692-02A (Recurrent Tumor).

[page 1 of 2]
Surg Path

CLINICAL HISTORY:

Metastatic serous adenocarcinoma of the ovary

GROSS EXAMINATION:

A. "Rectosigmoid pelvic tumor". Received is a 15 x 5 x 3 cm segment of sigmoid colon that shows a thick fibrous adherence consistent with tumor. The area involved by tumor is approximately 6 x 4 x 2 cm. The mucosal surface shows no gross abnormalities. The deep surface is inked blue.

BLOCK SUMMARY:

- A1-3 serosa and tumor
A4- representative of mucosa
A5- additional section of tumor

ICS-0-3
carcinoma serous 8441/3
Site: Ovary C56.9
pw
1/24/15

B. "Left obturator lymph node". A single 2.1 x 2 x 0.9 cm grossly positive lymph node candidate is received. Representative section is submitted as B1.

C. "Left pelvic sidewall". Received is a 5.5 x 3.2 x 1.2 cm segment of soft tissue that shows friable irregular soft tissue consistent with tumor. Representative sections are submitted in blocks C1-2.

D. "Ileocecal valve terminal ileum". Received is a 22 x 7 x average 1.5 cm length of terminal ileum with ileocecal valve, appendix and cecum. There are multiple abnormalities identified. First, there is a 2.2 x 1.5 cm friable tumor mass clustered on the serosa of the ileocecal valve and focally extruding into the mucosa of the cecum. In addition, there are five palpable positive lymph nodes in the serosa of the terminal ileum including one that ulcerates the overlying mucosa. The 4.2 x 1.5 cm vermiform appendix is swollen and adhered to the cecal serosa.

BLOCK SUMMARY:

- D1- tumor and ileocecal valve
D2- representative terminal ileum and serosal nodule
D3- representatives of appendix
D4- representative of tumor nodule in cecum

E. "Left peristomal hernia implant". A 5.5 x 1 x 0.8 cm strip of pink soft tissue is received. Representative sections are submitted as E1.

MICROSCOPIC EXAMINATION:

Microscopic examination is performed.

DIAGNOSIS:

A. "RECTOSIGMOID PELVIC TUMOR" (DEBULKING):

RECURRENT SEROUS ADENOCARCINOMA OF THE OVARY INVOLVING RECTUM AND SIGMOID COLON.

TUMOR SIZE: 6 X 4 X 2 CM.

MARGIN: NEGATIVE.

B. "LEFT OBTURATOR LYMPH NODE" (BIOPSY):

SINGLE LYMPH NODE WITH METASTATIC SEROUS ADENOCARCINOMA (1/1).
SIZE OF METASTASIS: 2.1 CM.

[page 2 of 2]
C. "LEFT PELVIC SIDEWALL" (BIOPSY):

METASTATIC SEROUS ADENOCARCINOMA.

D. "ILEOCECAL VALVE TERMINAL ILEUM" (DEBULKING):

RECURRENT SEROUS ADENOCARCINOMA OF THE OVARY INVOLVING ILEUM, CECUM AND APPENDIX.

E. "LEFT PERISTOMAL HERNIA IMPLANT" (BIOPSY):

FIBROUS TISSUE WITH NO EVIDENCE OF MALIGNANCY.

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

Performed by:

[REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file f22d3d93-2607-4c19-9dca-1a9d529211bb (TCGA-29-1692.FF9EECFF-66C4-440F-91AB-42ACCEED0A3B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).